Surgical pathology report (de-identified scan), TCGA case TCGA-34-5236, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-5236-01A (Primary Tumor).

FINAL DIAGNOSIS:

The left upper lobe demonstrates a 9.5 cm moderately differentiated squamous cell carcinoma with paraphrenic extension. No evidence of visceral pleural invasion. All sampled lymph nodes are benign. Surgical margins of resection are free of tumor. Pathologic stage is pT3N0Mx.

PART 1: LYMPH NODES, LEVEL 6, BIOPSY -
ONE (1) MINUTE BENIGN LYMPH NODE.

PART 2: BONE, 4TH RIB, RESECTION -
BONE WITH MILDLY HYPERCELLULAR BONE MARROW.

PART 3: LYMPH NODE, LEVEL 3, BIOPSY -
ONE (1) LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 4: LYMPH NODE, LEVEL 5, BIOPSY -
ONE (1) LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 5: "PARAPHRENIC EXTENSION" BIOPSY -
POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA. ✓

PART 6: PLEURA, MEDIASTINAL, BIOPSY -
UNREMARKABLE PLEURA.

PART 7: PLEURA, BIOPSY -
A. LYMPHOCYTIC PLEURITIS.
B. TWO (2) BENIGN LYMPH NODES.

PART 8: LUNG, LEFT UPPER LOBE, BIOPSY -
A. PLEURAL HYALINE PLAQUE WITH CALCIFICATION. (See comment)
B. PLEURAL ADHESIONS AND LYMPHOCYTIC PLEURITIS.

PART 9: LYMPH NODE, LEVEL 4, BIOPSY -
TWO (2) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 10: LYMPH NODE, LEVEL 7, BIOPSY -
FOUR (4) FRAGMENTS OF LYMPH NODE WITH ANTHRACOTIC PIGMENT.

PART 11: LUNG, LEFT, PNEUMONECTOMY -
A. INVASIVE MODERATE TO POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, (9.5 CM). NO EVIDENCE OF VISCERAL PLEURAL INVASION. MILD LYMPHOCYTIC HOST RESPONSE. ELEVEN (11) FRAGMENTS OF BENIGN N1 ANTHRACOTIC LYMPH NODES. PATHOLOGIC STAGE: pT3N0Mx.
B. SURGICAL MARGINS OF RESECTION ARE NEGATIVE FOR TUMOR. ✓
C. BACKGROUND LUNG WITH PLEURAL HYALINE PLAQUES, PLEURAL ADHESIONS, EMPHYSEMA AND PATHCY ACUTE PNEUMONIA. ✓

COMMENT:

Detached fragments of carcinoma identified in the part 8 most likely represent a tissue contaminant.

Source: NCI Genomic Data Commons file b80f07b5-47b5-489d-ba89-4faccb8f253c (TCGA-34-5236.8AADCD05-F598-4C12-87EB-6769BBF24B51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).